Somatic mutation profile of tumor specimen TCGA-UZ-A9PM-01A (aliquot TCGA-UZ-A9PM-01A-21D-A382-10) from TCGA case TCGA-UZ-A9PM, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II.
Specimen TCGA-UZ-A9PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95291e8b-9552-4915-8307-dc1f3ac8d2ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PM-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PM-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b23bec1f-14c9-418d-8723-587c1a3cee73

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 15, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTRAP | c.419A>C p.E140A | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100065560; called by muse, mutect2, varscan2
- AP4M1 | c.614T>A p.L205Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57999493; called by muse, mutect2, varscan2
- ARR3 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV99333867; called by muse, mutect2, varscan2
- ATP2C1 | c.2708A>T p.E903V | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100147001; called by muse, mutect2, varscan2
- C5 | c.3844G>A p.G1282S | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56326489; called by muse, mutect2, varscan2
- CCT4 | c.1230T>G p.C410W | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101075399; called by muse, mutect2, varscan2
- CD1D | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs757831900, COSV100939662; called by muse, mutect2, varscan2
- COL27A1 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.98); catalogued as COSV100621349; called by muse, mutect2
- COX15 | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99187706; called by muse, mutect2, varscan2
- CUX1 | c.3692A>C p.E1231A | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99473222; called by muse, mutect2, varscan2
- EFCAB1 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100031006; called by muse, mutect2, varscan2
- EIF4G1 | c.1496T>C p.L499S (on ENST00000346169 / NM_198241.3; = p.L303S on NM_004953.5) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs780235176, COSV100072327; called by muse, mutect2, varscan2
- FBXO42 | c.362C>G p.S121W | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100981947; called by mutect2, varscan2
- GPX4 | c.502-1G>T p.X168_splice | Splice Site (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100685043; called by muse, mutect2, varscan2
- HUWE1 | c.2150G>C p.R717T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.558); catalogued as COSV53362901, COSV99474340; called by muse, mutect2, varscan2
- ITGAD | c.1990C>A p.Q664K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV101210593; called by muse, mutect2, varscan2
- KANK1 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1326304483, COSV63217176; called by mutect2, varscan2
- KCTD16 | c.628A>T p.N210Y | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101568903; called by muse, mutect2, varscan2
- KIAA2013 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100927156; called by muse, mutect2, varscan2
- LRP6 | c.4175T>C p.F1392S | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373215297; called by muse, mutect2
- MEIOC | c.1694T>C p.L565P | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100740298; called by muse, mutect2, varscan2
- MUC16 | c.11449C>T p.L3817F | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.179); catalogued as COSV101201030; called by muse, mutect2, varscan2
- NEO1 | c.2583G>C p.Q861H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775994532, COSV56080256; called by muse, mutect2, varscan2
- NXT1 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99656418; called by muse, mutect2, varscan2
- OTUD4 | c.1041A>T p.K347N (on ENST00000447906 / NM_001366057.1; = p.K282N on NM_001102653.1) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV101486070; called by muse, mutect2, varscan2
- PARP14 | c.4702G>A p.D1568N | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV101506355; called by muse, mutect2, varscan2
- PARP14 | c.4703A>T p.D1568V | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs762330792, COSV101506356; called by muse, mutect2, varscan2
- PLXND1 | c.4102G>A p.E1368K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV100140443; called by muse, mutect2, varscan2
- POU3F4 | c.134del p.G45Efs*14 | Frame Shift Del (DEL) | VAF 29/92 reads (32%) | catalogued as COSV64541057; called by mutect2, pindel, varscan2
- PPP2R1B | c.1509T>G p.N503K | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100232408; called by muse, mutect2
- RBMS2 | c.730A>G p.M244V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as COSV100008702; called by muse, mutect2, varscan2
- RBSN | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99515550; called by muse, mutect2, varscan2
- RXFP1 | c.1465G>C p.G489R | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314239, COSV57048985, COSV57057394; called by muse, mutect2, varscan2
- S100A7L2 | c.47T>A p.M16K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs766028222, COSV100906942; called by muse, mutect2, varscan2
- SEC14L3 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV99307327; called by muse, varscan2
- SETBP1 | c.4207del p.E1403Rfs*28 | Frame Shift Del (DEL) | VAF 19/129 reads (15%) | catalogued as COSV56317835; called by mutect2, pindel, varscan2
- SFXN1 | c.406A>G p.R136G | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369440; called by muse, mutect2, varscan2
- SMAP2 | c.572-1G>T p.X191_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | catalogued as COSV101019356; called by muse, mutect2
- TMEM65 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 80/335 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99899400; called by muse, mutect2, varscan2
- VPS35L | c.98A>G p.H33R | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770385859, COSV99221782; called by muse, mutect2, varscan2
- ZIC2 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs765615222, COSV100891817; called by muse, varscan2
- ZNF423 | c.289C>T p.R97C (on ENST00000563137 / NM_001379286.1; = p.R89C on NM_015069.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs146233664; called by muse, mutect2, varscan2
- ZNF493 | c.1676G>T p.C559F | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1290525949, COSV100828949; called by muse, mutect2, varscan2
- ZNF518A | c.1319A>G p.Y440C | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs782107993, COSV100283752; called by muse, mutect2, varscan2
- NOTCH2 | c.5756C>A p.A1919E | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ADCY8 | c.2148G>A p.L716= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99654521; called by muse, mutect2, varscan2
- ANK3 | c.1782T>C p.A594= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99782510; called by muse, mutect2, varscan2
- APOBEC3G | c.675G>A p.E225= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs921831233, COSV101349115; called by muse, mutect2, varscan2
- BEST3 | c.558C>T p.I186= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs1382143875, COSV99876404; called by muse, mutect2, varscan2
- DIAPH1 | c.2097A>C p.G699= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99527298; called by muse, mutect2, varscan2
- DNAH7 | c.2556G>A p.R852= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs984350184, COSV56760112; called by muse, mutect2, varscan2
- ERCC2 | c.831C>T p.D277= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs547544775, COSV55544418, COSV99676529; called by muse, mutect2, varscan2
- GDPD5 | c.462G>T p.L154= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100409512; called by muse, mutect2, varscan2
- MACF1 | c.17511T>A p.I5837= (on ENST00000372915; = p.I3879= on NM_012090.5) | Silent (SNP) | VAF 43/216 reads (20%) | catalogued as COSV99247036; called by muse, mutect2, varscan2
- PLOD2 | c.192T>C p.Y64= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV99283341; called by muse, mutect2, varscan2
- PPP6R2 | c.1833G>A p.E611= (on ENST00000216061 / NM_001365836.1; = p.E584= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99324888; called by muse, mutect2, varscan2
- TMEM140 | c.477C>G p.A159= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV99313336; called by muse, mutect2, varscan2
- WNK2 | c.1807T>C p.L603= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs915397226, COSV99944803; called by muse, mutect2
- ZNF318 | c.3048G>A p.S1016= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs773080896, COSV58933639; called by muse, mutect2, varscan2
- ZNF658 | c.1875G>A p.T625= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs1325279040; called by muse, mutect2, varscan2
- ACHE | c.1723+93C>A | Intron (SNP) | VAF 20/229 reads (9%) | catalogued as COSV99574603; called by muse, mutect2
